Somatic mutation profile of tumor specimen MBCProject_2575_T2_WES (aliquot MBCProject_2575_T2_WES_1) from CMI case MBCProject_2575, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.8 years (13,440 days).
Specimen MBCProject_2575_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8b3e58c-7a4b-46d6-9900-8eda8957ae25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2575_SALIVA (Saliva), aliquot MBCProject_2575_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/661c3602-9690-46bd-a559-ccf9a6b1422f

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Splice Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C7orf57 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs200433005, COSV100817309, COSV62364505; called by muse, mutect2, varscan2
- CHTF18 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs377268098; called by muse, mutect2, varscan2
- DCLRE1A | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1301471048; called by muse, varscan2
- FABP7 | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1288604859, COSV62956919; called by muse, mutect2
- KCNA1 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1259861866; called by muse, mutect2, varscan2
- LTBP4 | c.3671C>T p.P1224L (on ENST00000308370 / NM_001042544.1; = p.P1187L on NM_003573.2) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs755741997; called by muse, mutect2, varscan2
- MTOR | c.7289G>T p.R2430M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63874542; called by mutect2, varscan2
- PCDHB15 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs782788911, COSV50886810; called by muse, mutect2, varscan2
- PIK3CG | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1377001952, COSV63248165; called by muse, mutect2, varscan2
- SCN4A | c.2234A>G p.H745R | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs762279435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662388; called by muse, mutect2, varscan2
- AASS | c.1605A>C p.K535N | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC138647.1 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRE1 | c.2626C>G p.L876V | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CIAO3 | c.824-11_844del p.X275_splice | Splice Site (DEL) | VAF 17/151 reads (11%) | called by mutect2, pindel
- FARP2 | c.1568G>T p.C523F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); called by mutect2, varscan2
- HMCN1 | c.6608T>A p.L2203H | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KCNU1 | c.904-1G>A p.X302_splice | Splice Site (SNP) | VAF 60/179 reads (34%) | called by muse, mutect2, varscan2
- MME | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- RUNX1 | c.8T>G p.I3S | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SEMA3D | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TGDS | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- USP35 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CCR4 | c.264C>T p.F88= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs775907855, COSV58383724; called by muse, mutect2, varscan2
- CLK1 | c.447G>A p.L149= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, varscan2
- HMGN1 | c.180A>G p.G60= | Silent (SNP) | VAF 34/277 reads (12%) | called by muse, mutect2, varscan2
- HTR1A | c.327C>T p.C109= | Silent (SNP) | VAF 60/415 reads (14%) | catalogued as COSV100109023; called by muse, mutect2, varscan2
- ILF3 | c.1644G>T p.G548= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- SKOR2 | c.2292C>T p.D764= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2
- TCF4 | c.1452C>T p.S484= | Silent (SNP) | VAF 47/359 reads (13%) | called by muse, mutect2, varscan2
- USP35 | c.486G>A p.L162= | Silent (SNP) | VAF 37/802 reads (5%) | called by muse, mutect2
- ZDHHC9 | c.66C>T p.T22= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs1435350571; called by muse, mutect2, varscan2
- ADGRE1 | c.*4C>T | 3'UTR (SNP) | VAF 38/231 reads (16%) | catalogued as rs752806916; called by muse, mutect2, varscan2
- SERF2 | c.*132A>G | 3'UTR (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
